Somatic mutation profile of cancer-model specimen HCM-BROD-0451-C15-85C (3D Organoid, passage 2; aliquot HCM-BROD-0451-C15-85C-01D-A82H-36), derived from the primary tumor of HCMI case HCM-BROD-0451-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.0 years (25,951 days).
Specimen HCM-BROD-0451-C15-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ad33cd0-e5c0-4fd9-8a22-72a8ab2ee638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0451-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0451-C15-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ba589b7-4423-42cb-b704-10260f89a1ae

The open-access MAF lists 260 somatic variants for this specimen: 185 protein-altering or splice-affecting, 66 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 66, Frame Shift Del 10, Nonsense Mutation 7, Intron 5, Frame Shift Ins 3, Splice Region 3, 5'UTR 3, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 410/863 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 1055/1301 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 322/348 reads (93%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 448/448 reads (100%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.1789G>A p.A597T (on ENST00000354273; = p.A653T on NM_016234.3) | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV100634554; called by muse, mutect2, varscan2
- ADAMTS7 | c.4879G>A p.D1627N | Missense Mutation (SNP) | VAF 136/422 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs760425808; called by muse, mutect2, varscan2
- ALKBH3 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1396120106; called by muse, mutect2, varscan2
- ANKRD35 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV100841869; called by muse, mutect2, varscan2
- B4GAT1 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 74/670 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1056654045; called by muse, mutect2, varscan2
- BCL9L | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 650/936 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV52682003, COSV99420569; called by muse, mutect2
- BSX | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 239/805 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379770999, COSV58005533; called by muse, mutect2, varscan2
- C2orf42 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs552906288, COSV52450411; called by muse, mutect2, varscan2
- CACNA1E | c.2485C>T p.R829* | Nonsense Mutation (SNP) | VAF 542/608 reads (89%) | catalogued as COSV62407983; called by muse, mutect2, varscan2
- CACNA1H | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 764/765 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781343756, COSV61993560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC144A | c.160T>G p.W54G | Missense Mutation (SNP) | VAF 242/560 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV61402430; called by muse, mutect2, varscan2
- CCDC88B | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 271/956 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs902503769; called by muse, mutect2, varscan2
- CDC7 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445634808; called by muse, mutect2
- CISD2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs757788592; called by muse, mutect2, varscan2
- CPN2 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 231/733 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV60470968; called by muse, mutect2, varscan2
- CPXM2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 214/784 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.025); catalogued as COSV99583548; called by muse, mutect2, varscan2
- CYSLTR2 | c.774G>C p.L258F | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1484341813; called by muse, mutect2
- DAGLA | c.1232C>G p.T411R | Missense Mutation (SNP) | VAF 80/719 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563788842, COSV57194790; called by muse, mutect2, varscan2
- DCC | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 344/344 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1218682249; called by muse, mutect2, varscan2
- DST | c.19619G>A p.R6540H (on ENST00000361203 / NM_001374722.1; = p.R4237H on NM_015548.5) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1450180469; called by muse, mutect2, varscan2
- EML1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs147904150; called by muse, mutect2, varscan2
- EPS15L1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 281/546 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs143789982; called by muse, varscan2
- FAM135B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 198/891 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335175102, COSV104372835; called by muse, mutect2, varscan2
- FRMPD1 | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 251/516 reads (49%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.765); catalogued as rs778737300; called by muse, mutect2, varscan2
- FRY | c.2984C>T p.S995F | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1037669672; called by muse, mutect2, varscan2
- GRIN2D | c.3353C>T p.S1118L | Missense Mutation (SNP) | VAF 207/862 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV53518101; called by muse, mutect2, varscan2
- H3C2 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 57/734 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as COSV52518318; called by muse, mutect2
- ILKAP | c.288A>C p.K96N | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV54517419; called by muse, mutect2
- ISYNA1 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 168/303 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs945866048, COSV54210264; called by muse, mutect2, varscan2
- KIT | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); catalogued as COSV99854787; called by muse, mutect2, varscan2
- LLGL1 | c.2786del p.P929Hfs*9 | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | catalogued as COSV100375381, COSV57499651; called by mutect2, varscan2
- LRP2 | c.6266C>T p.P2089L | Missense Mutation (SNP) | VAF 185/250 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401120823, COSV55579834; called by muse, mutect2, varscan2
- MAGEB1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs769417412; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 81/160 reads (51%) | catalogued as rs1180255648; called by mutect2, varscan2
- MKRN3 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs201431738, COSV58808348, COSV58809659; called by muse, mutect2, varscan2
- MYO7B | c.4984G>T p.D1662Y | Missense Mutation (SNP) | VAF 143/751 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV67347326; called by muse, mutect2, varscan2
- NCOA2 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 154/742 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292380324; called by muse, mutect2, varscan2
- NDUFAF2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as rs527366210; called by muse, mutect2
- NID1 | c.3494T>C p.F1165S | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1483484017; called by muse, mutect2, varscan2
- NLRP5 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 357/762 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs199475775, COSV66767095; ClinVar: not provided; called by muse, mutect2, varscan2
- NWD1 | c.3736G>A p.G1246S | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1186757679, COSV60353354; called by muse, mutect2, varscan2
- OSCAR | c.84C>T p.V28= | Splice Region (SNP) | VAF 176/668 reads (26%) | catalogued as COSV52928107; called by muse, mutect2, varscan2
- PADI3 | c.1574C>A p.T525N | Missense Mutation (SNP) | VAF 290/291 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100968433, COSV64934600; called by muse, mutect2, varscan2
- PDE1C | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 163/362 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as COSV58503226; called by muse, mutect2, varscan2
- PDE6B | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 322/451 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs747155909, COSV99727292; called by muse, mutect2, varscan2
- PHF21B | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 410/413 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs145536476; called by muse, mutect2, varscan2
- PKHD1L1 | c.9836G>A p.R3279H | Missense Mutation (SNP) | VAF 150/709 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs763295862; called by muse, mutect2, varscan2
- POTEJ | c.2634G>T p.K878N | Missense Mutation (SNP) | VAF 453/636 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1305340216; called by muse, mutect2, varscan2
- PROZ | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 90/386 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs144364121; called by muse, mutect2, varscan2
- PSAP | c.794G>C p.C265S | Missense Mutation (SNP) | VAF 130/384 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CD011650; called by muse, mutect2, varscan2
- ROR2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 221/387 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs142993413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPGRIP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 144/325 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs775239691, COSV52843900, COSV52857086; called by muse, mutect2, varscan2
- RRP12 | c.3519C>T p.G1173= | Splice Region (SNP) | VAF 139/383 reads (36%) | catalogued as rs758736893; called by muse, mutect2, varscan2
- SDR42E2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 248/402 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs781754917; called by muse, mutect2, varscan2
- SERPINI1 | c.248dup p.N83Kfs*3 | Frame Shift Ins (INS) | VAF 282/407 reads (69%) | catalogued as rs924930202; called by mutect2, pindel, varscan2
- SHISA2 | c.509C>G p.A170G | Missense Mutation (SNP) | VAF 66/880 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.578); catalogued as rs747139053; called by muse, mutect2
- SORCS3 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 391/865 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as rs1248897947; called by muse, mutect2, varscan2
- SPTBN4 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 151/610 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1483353008; called by muse, mutect2, varscan2
- ST8SIA1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs887287275; called by muse, mutect2, varscan2
- TBX3 | c.1261C>T p.R421W (on ENST00000257566 / NM_016569.4; = p.R401W on NM_005996.4) | Missense Mutation (SNP) | VAF 212/812 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs912240752, COSV57469992; called by muse, mutect2, varscan2
- TEP1 | c.5368C>T p.R1790C | Missense Mutation (SNP) | VAF 25/347 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs373543585, COSV99402345; called by muse, mutect2
- TMEM132C | c.2008T>A p.L670M | Missense Mutation (SNP) | VAF 260/372 reads (70%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV59415191, COSV59425975, COSV59436558; called by muse, mutect2, varscan2
- TMEM132D | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 105/411 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs201186278, COSV101242735; called by muse, mutect2, varscan2
- TTN | c.98857C>T p.R32953C (on ENST00000591111; = p.R25529C on NM_003319.4) | Missense Mutation (SNP) | VAF 88/317 reads (28%) | PolyPhen probably damaging (0.998); catalogued as rs879240376, COSV60202286; called by muse, mutect2, varscan2
- TTN | c.91114G>T p.D30372Y (on ENST00000591111; = p.D22948Y on NM_003319.4) | Missense Mutation (SNP) | VAF 93/252 reads (37%) | PolyPhen probably damaging (0.961); catalogued as COSV100592127; called by muse, mutect2, varscan2
- UNC93B1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 228/923 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57097599, COSV57100172, COSV57100967; called by muse, mutect2, varscan2
- VSTM2B | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 287/1139 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs1177773676; called by muse, mutect2, varscan2
- WDR35 | c.1227G>A p.T409= | Splice Region (SNP) | VAF 27/64 reads (42%) | catalogued as rs760691875; called by muse, mutect2, varscan2
- ZNF541 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 223/886 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.933); catalogued as rs905839231, COSV54542880; called by muse, mutect2, varscan2
- ZP3 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs370377360; called by muse, mutect2, varscan2
- ACSL5 | c.1790C>T p.A597V (on ENST00000354273; = p.A653V on NM_016234.3) | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADAMTS16 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.2135_2147del p.K712Mfs*2 | Frame Shift Del (DEL) | VAF 64/704 reads (9%) | called by mutect2, pindel
- ANO7 | c.216C>A p.S72R (on ENST00000274979; = p.S18R on NM_001001666.4) | Missense Mutation (SNP) | VAF 223/607 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, varscan2
- AP4E1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- APOB | c.4615G>A p.D1539N | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPM | c.10135T>G p.L3379V | Missense Mutation (SNP) | VAF 150/164 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BHLHA15 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 270/532 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, varscan2
- C2CD6 | c.370A>C p.I124L | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH13 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP54 | c.4730G>C p.S1577T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLIP1 | c.4273T>G p.F1425V (on ENST00000620786 / NM_001247997.1; = p.F1414V on NM_002956.2) | Missense Mutation (SNP) | VAF 32/439 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNGA3 | c.505T>G p.Y169D | Missense Mutation (SNP) | VAF 52/791 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- CNTNAP5 | c.1940C>G p.P647R | Missense Mutation (SNP) | VAF 64/756 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.146); called by muse, mutect2
- COG8 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 372/611 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- COL21A1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSNKA2IP | c.2096C>A p.P699Q | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- DMRTA1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 294/627 reads (47%) | called by muse, mutect2, varscan2
- DNAH12 | c.4336A>T p.N1446Y (on ENST00000351747; = p.N1469Y on NM_001366028.2) | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DNAH9 | c.4162C>A p.Q1388K | Missense Mutation (SNP) | VAF 266/517 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DNAI2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2
- DOCK5 | c.5033C>G p.S1678C | Missense Mutation (SNP) | VAF 91/310 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EP400 | c.2318A>C p.K773T | Missense Mutation (SNP) | VAF 46/546 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- ETFBKMT | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FBN2 | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 274/437 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO38 | c.2499G>T p.R833S | Missense Mutation (SNP) | VAF 71/784 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.883); called by muse, mutect2
- FOLR2 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 327/812 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- FRY | c.2983T>A p.S995T | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GIPR | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 155/653 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GLYR1 | c.1569_1573del p.M523Ifs*5 | Frame Shift Del (DEL) | VAF 34/259 reads (13%) | called by mutect2, pindel, varscan2
- GRM5 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 96/392 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, varscan2
- GTF2F1 | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HDAC2 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECTD4 | c.7574T>G p.L2525R | Missense Mutation (SNP) | VAF 45/533 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC2 | c.13775C>T p.T4592I | Missense Mutation (SNP) | VAF 218/358 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- HIP1R | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.119); called by muse, mutect2
- HIVEP1 | c.1840T>C p.S614P | Missense Mutation (SNP) | VAF 168/452 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HMCN1 | c.11675C>G p.T3892S | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- HNRNPUL1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 359/1383 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HRC | c.1257C>A p.H419Q | Missense Mutation (SNP) | VAF 68/685 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HSPA1L | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 144/418 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGLV1-36 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 187/411 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IRS4 | c.3650C>A p.P1217H | Missense Mutation (SNP) | VAF 226/526 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- IRS4 | c.3649C>A p.P1217T | Missense Mutation (SNP) | VAF 228/532 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- IRX1 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 388/698 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGAD | c.1784A>G p.Q595R | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2
- KCNA7 | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); called by muse, mutect2
- KCNU1 | c.3394A>C p.K1132Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT76 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 340/732 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); called by muse, varscan2
- LGALS4 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMTK3 | c.2704G>A p.G902S | Missense Mutation (SNP) | VAF 216/769 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LRRC37A3 | c.4757T>C p.L1586S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- MRC1 | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 197/408 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR8 | c.1985A>T p.E662V | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2
- MUC16 | c.20977_20987del p.R6993Pfs*137 | Frame Shift Del (DEL) | VAF 41/293 reads (14%) | called by mutect2, pindel, varscan2
- MUC16 | c.7916C>G p.S2639C | Missense Mutation (SNP) | VAF 160/259 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYO15B | c.3542_3543del p.H1181Lfs*5 | Frame Shift Del (DEL) | VAF 161/477 reads (34%) | called by mutect2, pindel, varscan2
- MYRFL | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- NACA | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- NDST2 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 53/613 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NHSL1 | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- NIPA2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 48/75 reads (64%) | called by muse, mutect2, varscan2
- NIPA2 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NLE1 | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 170/377 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NLRP10 | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2
- NOBOX | c.1586A>T p.Q529L | Missense Mutation (SNP) | VAF 187/429 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- OLIG1 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 48/728 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR5AN1 | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 27/469 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- OR8H3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2
- PAK1IP1 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PASK | c.1488C>A p.S496R | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH9 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHAC2 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2
- PCDHB10 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 133/1123 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PFKFB2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 40/198 reads (20%) | PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- PPFIA1 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 38/750 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2
- PPFIA2 | c.601A>T p.R201* | Nonsense Mutation (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- PRPF3 | c.575C>G p.A192G | Missense Mutation (SNP) | VAF 47/542 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- PRPF40B | c.19-1G>C p.X7_splice (on ENST00000380281; = p.X1_splice on NM_012272.3) | Splice Site (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- PTPN23 | c.3022G>C p.G1008R | Missense Mutation (SNP) | VAF 49/486 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRA | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 63/706 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTPRD | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 197/393 reads (50%) | called by muse, mutect2, varscan2
- PXDN | c.2054T>A p.L685H | Missense Mutation (SNP) | VAF 264/371 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RILP | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- RP1 | c.947T>G p.F316C | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.12558G>A p.M4186I | Missense Mutation (SNP) | VAF 117/441 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SCAF1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 150/1098 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SGCZ | c.864T>A p.N288K | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SIDT1 | c.321_342del p.Q107Hfs*12 | Frame Shift Del (DEL) | VAF 193/213 reads (91%) | called by mutect2, pindel, varscan2
- SIGLEC8 | c.638dup p.P215Afs*61 | Frame Shift Ins (INS) | VAF 181/855 reads (21%) | called by mutect2, pindel, varscan2
- SLC16A4 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC26A11 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 293/656 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SLCO1B1 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SPAG9 | c.3875T>G p.L1292R (on ENST00000262013 / NM_001130528.3; = p.L1278R on NM_003971.6) | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTA1 | c.5443T>G p.L1815V | Missense Mutation (SNP) | VAF 189/190 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAT6 | c.1741del p.D581Mfs*6 | Frame Shift Del (DEL) | VAF 39/365 reads (11%) | called by mutect2, pindel
- SYNE1 | c.17185del p.Q5729Sfs*19 (on ENST00000367255 / NM_182961.4; = p.Q5658Sfs*19 on NM_033071.3) | Frame Shift Del (DEL) | VAF 36/248 reads (15%) | called by mutect2, pindel, varscan2
- TEFM | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 515/517 reads (100%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.6274T>A p.S2092T | Missense Mutation (SNP) | VAF 113/628 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAV26-1 | c.18A>C p.R6S | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRDN | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.499); called by muse, mutect2
- TRERF1 | c.1811A>G p.N604S | Missense Mutation (SNP) | VAF 296/790 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP27X | c.1148G>C p.S383T | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- VAMP3 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 31/418 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- XIRP1 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZBED9 | c.892del p.I298Yfs*45 | Frame Shift Del (DEL) | VAF 51/372 reads (14%) | called by mutect2, pindel, varscan2
- ZNF10 | c.1699C>G p.H567D | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF229 | c.1667G>T p.S556I | Missense Mutation (SNP) | VAF 188/668 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF263 | c.1238A>T p.E413V | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2
- ZNF649 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 30/580 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ZNF728 | c.1850G>C p.G617A | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADCY8 | c.1263A>G p.K421= | Silent (SNP) | VAF 20/570 reads (4%) | catalogued as rs1276388550; called by muse, mutect2
- AGRN | c.1512C>T p.S504= | Silent (SNP) | VAF 260/668 reads (39%) | catalogued as rs527601442; ClinVar: likely benign; called by muse, varscan2
- AMY2A | c.1149A>G p.K383= | Silent (SNP) | VAF 21/732 reads (3%) | called by muse, mutect2
- ANK2 | c.126C>G p.G42= | Silent (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- ASB18 | c.1008C>T p.T336= | Silent (SNP) | VAF 272/897 reads (30%) | called by muse, mutect2, varscan2
- ATP12A | c.2829C>G p.V943= | Silent (SNP) | VAF 40/742 reads (5%) | called by muse, mutect2
- C7orf26 | c.139C>T p.L47= | Silent (SNP) | VAF 109/866 reads (13%) | catalogued as COSV100254046; called by muse, mutect2, varscan2
- CAMTA2 | c.1215C>T p.A405= | Silent (SNP) | VAF 109/599 reads (18%) | catalogued as rs200943343, COSV61837156; called by muse, mutect2, varscan2
- CCDC47 | c.33T>A p.L11= | Silent (SNP) | VAF 128/276 reads (46%) | called by muse, varscan2
- CHAF1A | c.267G>A p.P89= | Silent (SNP) | VAF 128/208 reads (62%) | catalogued as rs144939143; called by muse, mutect2, varscan2
- COL6A1 | c.756C>T p.C252= | Silent (SNP) | VAF 354/723 reads (49%) | called by muse, mutect2
- CRACDL | c.2307G>A p.Q769= | Silent (SNP) | VAF 248/800 reads (31%) | called by muse, mutect2, varscan2
- CRYBG3 | c.3357G>A p.G1119= | Silent (SNP) | VAF 83/188 reads (44%) | catalogued as COSV51711053; called by muse, mutect2, varscan2
- DEFB115 | c.177T>C p.C59= | Silent (SNP) | VAF 91/291 reads (31%) | catalogued as COSV101269331; called by muse, mutect2, varscan2
- DNHD1 | c.4563C>T p.A1521= | Silent (SNP) | VAF 351/351 reads (100%) | catalogued as rs907194185; called by muse, mutect2, varscan2
- DUXB | c.480G>A p.K160= | Silent (SNP) | VAF 74/217 reads (34%) | catalogued as rs1239855527; called by muse, mutect2, varscan2
- EPHB2 | c.2385G>A p.P795= (on ENST00000400191 / NM_001309193.2; = p.P796= on NM_004442.7) | Silent (SNP) | VAF 242/430 reads (56%) | catalogued as rs747690195; called by muse, mutect2, varscan2
- ERC2 | c.1878A>G p.K626= | Silent (SNP) | VAF 154/154 reads (100%) | called by muse, mutect2, varscan2
- FASTKD1 | c.759T>C p.N253= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- FBN2 | c.7068C>T p.N2356= | Silent (SNP) | VAF 24/328 reads (7%) | catalogued as rs1554117256; ClinVar: likely benign; called by muse, mutect2
- GLE1 | c.39C>T p.A13= | Silent (SNP) | VAF 187/408 reads (46%) | called by muse, mutect2, varscan2
- GMIP | c.769C>A p.R257= | Silent (SNP) | VAF 264/537 reads (49%) | called by muse, mutect2, varscan2
- GMIP | c.768G>A p.S256= | Silent (SNP) | VAF 270/547 reads (49%) | called by muse, mutect2, varscan2
- GRIN2D | c.2262C>T p.D754= | Silent (SNP) | VAF 99/469 reads (21%) | catalogued as rs769986115; called by muse, mutect2, varscan2
- GYS1 | c.255G>C p.P85= | Silent (SNP) | VAF 162/733 reads (22%) | catalogued as rs146417520; called by muse, mutect2, varscan2
- H1-5 | c.87C>T p.A29= | Silent (SNP) | VAF 389/566 reads (69%) | catalogued as rs762937170; called by muse, mutect2
- H3C12 | c.297C>G p.A99= | Silent (SNP) | VAF 85/570 reads (15%) | called by muse, mutect2, varscan2
- HEATR4 | c.2113C>T p.L705= | Silent (SNP) | VAF 104/201 reads (52%) | called by muse, mutect2, varscan2
- HLA-G | c.886C>T p.L296= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as rs1438202915, COSV64407261; called by muse, mutect2
- HSPA1L | c.1233G>A p.V411= | Silent (SNP) | VAF 136/404 reads (34%) | called by muse, varscan2
- ITGB6 | c.1071C>G p.S357= | Silent (SNP) | VAF 73/261 reads (28%) | catalogued as COSV99324624; called by muse, mutect2, varscan2
- ITIH4 | c.2562G>A p.G854= | Silent (SNP) | VAF 513/513 reads (100%) | catalogued as COSV56574477; called by muse, mutect2, varscan2
- JPH1 | c.1072A>C p.R358= | Silent (SNP) | VAF 158/851 reads (19%) | called by muse, mutect2, varscan2
- KIF13A | c.2208A>G p.K736= | Silent (SNP) | VAF 26/436 reads (6%) | called by muse, mutect2
- KNDC1 | c.978C>T p.R326= | Silent (SNP) | VAF 438/648 reads (68%) | catalogued as rs769961561, COSV58832421; called by muse, mutect2, varscan2
- LRRC14B | c.871C>T p.L291= | Silent (SNP) | VAF 318/574 reads (55%) | catalogued as rs753057916; called by muse, mutect2, varscan2
- LTBP2 | c.801G>A p.S267= | Silent (SNP) | VAF 200/488 reads (41%) | catalogued as rs760646352; called by muse, varscan2
- MARF1 | c.4905C>A p.S1635= | Silent (SNP) | VAF 104/659 reads (16%) | catalogued as COSV100705714; called by muse, mutect2, varscan2
- NCKAP5L | c.153C>T p.N51= | Silent (SNP) | VAF 87/331 reads (26%) | catalogued as rs375380248; called by muse, mutect2, varscan2
- NOTCH3 | c.3393C>T p.C1131= | Silent (SNP) | VAF 270/466 reads (58%) | catalogued as CM081358; called by muse, mutect2, varscan2
- NOVA1 | c.639G>A p.G213= | Silent (SNP) | VAF 175/365 reads (48%) | catalogued as COSV57480155; called by muse, mutect2, varscan2
- NRXN2 | c.594C>T p.R198= | Silent (SNP) | VAF 318/1042 reads (31%) | called by muse, mutect2, varscan2
- ODR4 | c.990A>T p.P330= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- OTOG | c.3507C>T p.A1169= | Silent (SNP) | VAF 112/415 reads (27%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1117A>C p.R373= | Silent (SNP) | VAF 196/549 reads (36%) | catalogued as COSV50753829; called by muse, mutect2, varscan2
- PLSCR4 | c.585C>T p.C195= | Silent (SNP) | VAF 46/402 reads (11%) | catalogued as rs772540798; called by muse, mutect2, varscan2
- PRF1 | c.1002C>A p.G334= | Silent (SNP) | VAF 242/774 reads (31%) | called by muse, mutect2, varscan2
- PRG3 | c.381C>T p.V127= | Silent (SNP) | VAF 107/368 reads (29%) | called by muse, mutect2, varscan2
- PTPRS | c.1296C>T p.N432= | Silent (SNP) | VAF 334/577 reads (58%) | called by muse, mutect2, varscan2
- PTPRT | c.426C>T p.V142= | Silent (SNP) | VAF 181/725 reads (25%) | catalogued as rs1569159197; called by muse, mutect2, varscan2
- RAG1 | c.2667C>T p.Y889= | Silent (SNP) | VAF 240/445 reads (54%) | called by muse, mutect2, varscan2
- RALGAPB | c.2811G>T p.L937= | Silent (SNP) | VAF 111/462 reads (24%) | called by muse, mutect2, varscan2
- RBMXL3 | c.936C>T p.G312= | Silent (SNP) | VAF 608/609 reads (100%) | catalogued as rs782770623, COSV100407533; called by muse, mutect2, varscan2
- S1PR5 | c.702G>A p.G234= | Silent (SNP) | VAF 227/627 reads (36%) | catalogued as rs1164772782, COSV61014502; called by muse, mutect2, varscan2
- SALL3 | c.90G>A p.P30= | Silent (SNP) | VAF 92/623 reads (15%) | catalogued as rs762052260, COSV101609916; called by muse, mutect2, varscan2
- SDHAF1 | c.276T>C p.P92= | Silent (SNP) | VAF 301/1155 reads (26%) | called by muse, mutect2, varscan2
- SEMA4B | c.951C>T p.F317= | Silent (SNP) | VAF 52/1265 reads (4%) | called by muse, mutect2
- SSTR2 | c.798C>T p.I266= | Silent (SNP) | VAF 50/534 reads (9%) | catalogued as rs764470922; called by muse, mutect2
- SYCP2 | c.2178G>A p.S726= | Silent (SNP) | VAF 174/284 reads (61%) | catalogued as rs781040014, COSV62770547; called by muse, mutect2, varscan2
- TAS1R1 | c.1758C>T p.G586= | Silent (SNP) | VAF 365/652 reads (56%) | called by muse, varscan2
- TBCCD1 | c.1452G>A p.G484= | Silent (SNP) | VAF 22/536 reads (4%) | called by muse, mutect2
- TFCP2L1 | c.852C>T p.L284= | Silent (SNP) | VAF 42/356 reads (12%) | catalogued as rs140322957; called by muse, mutect2, varscan2
- TLN2 | c.2946G>A p.L982= | Silent (SNP) | VAF 156/266 reads (59%) | called by muse, mutect2, varscan2
- TRIM49 | c.1032G>A p.E344= | Silent (SNP) | VAF 83/616 reads (13%) | catalogued as COSV99052207; called by muse, mutect2, varscan2
- ZNF177 | c.586A>C p.R196= | Silent (SNP) | VAF 80/245 reads (33%) | catalogued as rs1305173605; called by muse, mutect2, varscan2
- ZNF514 | c.93G>C p.L31= | Silent (SNP) | VAF 32/534 reads (6%) | called by muse, mutect2
- AL162417.1 | c.397-18892C>G | Intron (SNP) | VAF 360/708 reads (51%) | catalogued as rs1452624461; called by muse, mutect2, varscan2
- BTBD9 | c.1155-57740G>T | Intron (SNP) | VAF 34/329 reads (10%) | called by muse, mutect2, varscan2
- COL6A5 | c.-364C>T | 5'UTR (SNP) | VAF 40/302 reads (13%) | called by muse, mutect2, varscan2
- COL6A5 | c.-363C>G | 5'UTR (SNP) | VAF 39/301 reads (13%) | called by muse, mutect2, varscan2
- JMJD8 | c.-1C>T | 5'UTR (SNP) | VAF 890/895 reads (99%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345586 T>A | 5'Flank (SNP) | VAF 32/620 reads (5%) | called by muse, mutect2
- NIPAL3 | c.1021+1931T>C | Intron (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+963C>T | Intron (SNP) | VAF 533/533 reads (100%) | called by muse, mutect2, varscan2
- ZNF324B | c.238+95T>A | Intron (SNP) | VAF 436/629 reads (69%) | called by muse, mutect2, varscan2
